Somatic mutation profile of tumor specimen TCGA-3A-A9IC-01A (aliquot TCGA-3A-A9IC-01A-11D-A38G-08) from TCGA case TCGA-3A-A9IC, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.3 years (22,400 days).
Specimen TCGA-3A-A9IC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65621f68-47fe-431e-9acf-6883c23cf8b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IC-10A (Blood Derived Normal), aliquot TCGA-3A-A9IC-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa90b3fd-7ef4-412d-9367-1a2df9da07f4

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 53/288 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs557075212, COSV53912260; called by muse, mutect2, varscan2
- ALAS2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100238156; called by muse, mutect2
- ARSF | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV100839471; called by muse, mutect2, varscan2
- ASPM | c.7996A>G p.T2666A | Missense Mutation (SNP) | VAF 111/360 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.241); catalogued as rs1195117565, COSV99660027; called by muse, mutect2, varscan2
- DNAJC30 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 84/508 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV56095741; called by muse, mutect2, varscan2
- DOCK9 | c.746A>G p.E249G (on ENST00000376460 / NM_001366676.2; = p.E250G on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1466848812, COSV100238693; called by muse, mutect2
- DPP6 | c.1247G>A p.G416E (on ENST00000377770 / NM_001364500.2; = p.G354E on NM_001936.5) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207091536, COSV100124409, COSV100125881; called by muse, mutect2, varscan2
- MUC16 | c.24377C>T p.T8126I | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV101199283; called by muse, mutect2, varscan2
- MUC17 | c.12344C>T p.T4115M | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.046); catalogued as rs756321309, COSV60285753; called by muse, mutect2, varscan2
- OR7D4 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1462024302, COSV100432664; called by muse, mutect2, varscan2
- PCDHB12 | c.882T>G p.I294M | Missense Mutation (SNP) | VAF 54/732 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs1206498589, COSV99507065; called by muse, mutect2
- PMS1 | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 110/597 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV100575565; called by muse, mutect2, varscan2
- PRDM11 | c.1123G>A p.A375T (on ENST00000530656 / NM_001359633.1; = p.A341T on NM_001256695.1) | Missense Mutation (SNP) | VAF 131/715 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1323975198, COSV55440529; called by muse, mutect2, varscan2
- PTPRM | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.009); catalogued as rs1265059295, COSV100156324; called by muse, mutect2, varscan2
- REV3L | c.5715G>C p.Q1905H | Missense Mutation (SNP) | VAF 74/611 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100725071; called by muse, mutect2, varscan2
- SLC22A11 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 62/301 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs554874803, COSV100102260, COSV57251894; called by muse, mutect2, varscan2
- SYNE1 | c.3889G>A p.A1297T (on ENST00000367255 / NM_182961.4; = p.A1304T on NM_033071.3) | Missense Mutation (SNP) | VAF 53/344 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs781769990, COSV99549415; called by muse, mutect2, varscan2
- TCEAL2 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 100/619 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100216278; called by muse, mutect2, varscan2
- TGFBR2 | c.1577A>T p.E526V | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55458062, COSV99846807; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 56/343 reads (16%) | catalogued as rs587780067; called by pindel, varscan2
- TPSD1 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs1170737616, COSV99273737; called by muse, varscan2
- TRIM51 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99792405; called by muse, mutect2, varscan2
- UVRAG | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 36/844 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316137223, COSV62102259; called by muse, mutect2
- ZKSCAN3 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 85/525 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs765890348, COSV99356856; called by muse, mutect2, varscan2
- ZNF302 | c.1060C>T p.H354Y (on ENST00000627982; = p.H275Y on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 149/554 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs751655910, COSV101416460; called by muse, mutect2, varscan2
- ZNF507 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 114/476 reads (24%) | catalogued as COSV61330044; called by muse, mutect2, varscan2
- ANKAR | c.3591A>G p.V1197= | Silent (SNP) | VAF 82/486 reads (17%) | catalogued as rs1171282723, COSV99854082; called by muse, mutect2, varscan2
- ATP10A | c.2973C>T p.F991= | Silent (SNP) | VAF 38/245 reads (16%) | catalogued as COSV100791056; called by muse, mutect2, varscan2
- CDC14A | c.1453C>T p.L485= | Silent (SNP) | VAF 49/240 reads (20%) | catalogued as COSV60563439; called by muse, mutect2, varscan2
- DMD | c.2781C>T p.A927= | Silent (SNP) | VAF 45/267 reads (17%) | catalogued as COSV100819031; called by muse, mutect2, varscan2
- KCNH6 | c.918C>T p.I306= | Silent (SNP) | VAF 121/601 reads (20%) | catalogued as rs770277861, COSV59008607; called by muse, mutect2, varscan2
- LPAR6 | c.219G>A p.R73= | Silent (SNP) | VAF 41/186 reads (22%) | catalogued as COSV99924086; called by muse, mutect2, varscan2
- SLC6A2 | c.1227C>T p.F409= | Silent (SNP) | VAF 141/725 reads (19%) | catalogued as rs149035289; called by muse, mutect2, varscan2
- TCERG1 | c.675C>T p.A225= | Silent (SNP) | VAF 51/169 reads (30%) | catalogued as rs1260789669, COSV99694645; called by muse, mutect2, varscan2
- VAV3 | c.354A>T p.T118= | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as COSV100579511; called by muse, mutect2, varscan2
- MITF | c.352-1096C>T | Intron (SNP) | VAF 14/228 reads (6%) | catalogued as COSV100096772; called by muse, mutect2
